Somatic mutation profile of tumor specimen TARGET-20-PASHWN-04A (aliquot TARGET-20-PASHWN-04A-01D) from TARGET case TARGET-20-PASHWN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.1 years (2,606 days).
Specimen TARGET-20-PASHWN-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8c3adc6-b522-4e82-b84c-c2907fdf03d9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASHWN-14A (Bone Marrow Normal), aliquot TARGET-20-PASHWN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6c8d394-ab63-42f6-8144-a049c82208d2

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 2, Missense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 16/48 reads (33%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TDRD6 | c.832C>G p.R278G | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.938); catalogued as rs145478407, COSV60175563; called by mutect2, varscan2
- WT1 | c.1094_1106dup p.A370Sfs*7 | Frame Shift Ins (INS) | VAF 30/68 reads (44%) | catalogued as COSV60066438, COSV60071255, COSV60072670, COSV60072961, COSV60074589; called by mutect2, varscan2
- TRO | c.421A>G p.K141E | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- CACNA1B | c.*1006C>T | 3'UTR (SNP) | VAF 12/173 reads (7%) | catalogued as rs1157273571; called by muse, mutect2
